Somatic mutation profile of tumor specimen TCGA-K1-A3PN-01A (aliquot TCGA-K1-A3PN-01A-11D-A228-09) from TCGA case TCGA-K1-A3PN, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Uterus, NOS; Age at diagnosis: 64.7 years (23,631 days).
Specimen TCGA-K1-A3PN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef88944f-2e16-48f7-bb16-4c1a11c4742e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-K1-A3PN-10A (Blood Derived Normal), aliquot TCGA-K1-A3PN-10A-01D-A22A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc1bb4c3-860d-44b7-bc40-5c2863101e6c

The open-access MAF lists 38 somatic variants for this specimen: 26 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 10, Nonsense Mutation 2, RNA 1, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.713G>A p.C238Y | Missense Mutation (SNP) | VAF 34/41 reads (83%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882005, CM034930, COSV52661646, COSV52706816, COSV52804264; ClinVar: likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ACSL4 | c.815T>A p.M272K (on ENST00000340800 / NM_022977.2; = p.M231K on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.074); catalogued as COSV100539145; called by muse, mutect2, varscan2
- ALOX15B | c.540G>T p.K180N | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV66480298; called by muse, mutect2, varscan2
- CDHR3 | c.2349T>A p.D783E | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100488208, COSV58419658; called by muse, mutect2, varscan2
- CTTN | c.926A>G p.K309R | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0.075); catalogued as COSV100097530; called by muse, mutect2, varscan2
- DGAT2 | c.833C>T p.S278F | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99930045; called by muse, mutect2, varscan2
- DLGAP1 | c.1516G>A p.D506N | Missense Mutation (SNP) | VAF 51/100 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as rs1298416995, COSV59793093; called by muse, mutect2, varscan2
- DNAI4 | c.1717C>T p.P573S | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.051); catalogued as COSV100925270; called by muse, mutect2, varscan2
- FAM83B | c.1477C>T p.R493C | Missense Mutation (SNP) | VAF 23/25 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs373419492; called by muse, mutect2, varscan2
- HMGCS1 | c.1189G>T p.A397S | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100284970; called by muse, mutect2, varscan2
- HUWE1 | c.3505A>G p.T1169A | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0.111); catalogued as COSV99471735; called by muse, mutect2, varscan2
- IK | c.1182G>T p.M394I | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV101341776; called by muse, mutect2, varscan2
- LTBP4 | c.3354C>A p.C1118* (on ENST00000308370 / NM_001042544.1; = p.C1081* on NM_003573.2) | Nonsense Mutation (SNP) | VAF 68/146 reads (47%) | catalogued as COSV99199738; called by muse, mutect2, varscan2
- MAGEA11 | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1163894836, COSV100290460; called by muse, mutect2, varscan2
- MID2 | c.2054T>C p.L685P | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.864); catalogued as COSV99465784; called by muse, mutect2, varscan2
- MYH1 | c.3748G>T p.E1250* | Nonsense Mutation (SNP) | VAF 22/486 reads (5%) | catalogued as COSV99877090; called by muse, mutect2
- OR8U1 | c.754T>C p.Y252H | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV100164163; called by muse, mutect2, varscan2
- PLCG1 | c.1010+1G>T p.X337_splice | Splice Site (SNP) | VAF 55/98 reads (56%) | catalogued as COSV54817249, COSV99718743; called by muse, mutect2, varscan2
- PRRT3 | c.927G>T p.Q309H | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.371); catalogued as COSV99926464; called by muse, varscan2
- RIPPLY3 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.726); catalogued as COSV100289461; called by muse, mutect2
- SEPTIN14 | c.467C>A p.S156Y | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV66429255; called by muse, mutect2, varscan2
- SLC12A8 | c.1619C>T p.S540F | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV100103231; called by muse, mutect2, varscan2
- SPO11 | c.978T>A p.D326E | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.011); catalogued as COSV100625683; called by muse, mutect2, varscan2
- TAF4 | c.1613C>T p.A538V | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.065); catalogued as COSV99435209; called by muse, mutect2, varscan2
- USP54 | c.3929A>G p.Q1310R | Missense Mutation (SNP) | VAF 43/84 reads (51%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.007); catalogued as COSV100357670; called by muse, mutect2, varscan2
- TRAV26-1 | c.20T>G p.V7G | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- AP3D1 | c.1848A>T p.P616= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV100642603; called by muse, mutect2, varscan2
- FAM167B | c.183A>G p.K61= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as rs1474699619, COSV100406042; called by muse, mutect2, varscan2
- KRT32 | c.1162C>A p.R388= | Silent (SNP) | VAF 31/67 reads (46%) | catalogued as COSV56787394, COSV99862990; called by muse, mutect2, varscan2
- MDN1 | c.12228C>A p.P4076= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as COSV101021905; called by muse, mutect2
- OR52W1 | c.918A>G p.R306= | Silent (SNP) | VAF 28/52 reads (54%) | catalogued as COSV100258633; called by muse, mutect2, varscan2
- SCN4A | c.2886G>A p.S962= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as rs779571330, COSV71128599; called by muse, mutect2, varscan2
- SMCHD1 | c.18C>T p.G6= | Silent (SNP) | VAF 24/52 reads (46%) | catalogued as COSV99861385; called by muse, mutect2, varscan2
- SPECC1L | c.2415C>T p.G805= | Silent (SNP) | VAF 4/69 reads (6%) | catalogued as COSV100063467; called by muse, mutect2
- UCKL1 | c.165C>T p.R55= | Silent (SNP) | VAF 17/110 reads (15%) | catalogued as rs371274737, COSV100700591; called by muse, mutect2, varscan2
- ZNF26 | c.1359C>A p.P453= | Silent (SNP) | VAF 6/126 reads (5%) | called by muse, mutect2
- DCHS2 | n.1899T>C | RNA (SNP) | VAF 19/44 reads (43%) | catalogued as COSV100251566; called by muse, mutect2, varscan2
- MFSD4B | c.*46A>T | 3'UTR (SNP) | VAF 12/35 reads (34%) | catalogued as COSV100920569; called by muse, mutect2, varscan2
